Somatic mutation profile of tumor specimen TCGA-Z5-AAPL-01A (aliquot TCGA-Z5-AAPL-01A-12D-A40W-08) from TCGA case TCGA-Z5-AAPL, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 74.3 years (27,152 days).
Specimen TCGA-Z5-AAPL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d116b5b4-3dff-492c-a7db-5a3ed51cd880.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z5-AAPL-10A (Blood Derived Normal), aliquot TCGA-Z5-AAPL-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efbc2d57-7431-4fec-98f3-1a815df72184

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 12/328 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- DIDO1 | c.3893C>T p.T1298M | Missense Mutation (SNP) | VAF 40/656 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs558826220, COSV99826488; called by muse, mutect2
- ERICH3 | c.1567A>G p.M523V | Missense Mutation (SNP) | VAF 20/666 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV100445042; called by muse, mutect2
- FAT1 | c.11858G>T p.G3953V | Missense Mutation (SNP) | VAF 14/397 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499466; called by muse, mutect2
- PBRM1 | c.2779+2T>C p.X927_splice | Splice Site (SNP) | VAF 5/98 reads (5%) | catalogued as COSV99969955; called by muse, mutect2
- RAPGEF2 | c.2875A>T p.S959C | Missense Mutation (SNP) | VAF 30/607 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100031424; called by muse, mutect2
- PAOX | c.204G>A p.A68= | Silent (SNP) | VAF 15/294 reads (5%) | catalogued as COSV53372619; called by muse, mutect2
- SOGA3 | c.2061C>T p.H687= | Silent (SNP) | VAF 16/520 reads (3%) | catalogued as COSV100846996; called by muse, mutect2
